Somatic mutation profile of tumor specimen TCGA-EL-A4JV-01A (aliquot TCGA-EL-A4JV-01A-11D-A257-08) from TCGA case TCGA-EL-A4JV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.2 years (15,065 days).
Specimen TCGA-EL-A4JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb3c7004-f217-4bd8-97e9-a9bc834a6749.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4JV-11A (Solid Tissue Normal), aliquot TCGA-EL-A4JV-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e070a8ed-a3d0-4e31-866b-e3792c679a8f

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 31/81 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP2A2 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV59961861; called by muse, mutect2
- DISP3 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53830956; called by muse, mutect2, varscan2
- LILRB1 | c.1669G>A p.A557T (on ENST00000427581; = p.A507T on NM_006669.6) | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as rs772832622, COSV61121902; called by muse, mutect2, varscan2
- MYH13 | c.4156C>T p.R1386C | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs755466170, COSV52823329, COSV52828115; called by muse, mutect2, varscan2
- TDRD5 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV54245863; called by muse, mutect2, varscan2
